Gene-level copy-number profile of specimen HCM-SANG-0307-C15-85A from HCMI case HCM-SANG-0307-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0307-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cefdab3d-bf29-4af9-8d45-252b35c249aa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0307-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/4b362fa9-4031-4404-8522-cf19308dea49

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 4,545; copy number 3: 200; copy number 4: 25,653; copy number 5: 2,557; copy number 6: 18,813; copy number 7: 455; copy number 8: 4,468; copy number 9: 1,228; copy number 10: 756; copy number 11: 12; copy number 12: 22; copy number 15: 5; copy number 17: 55; copy number 18: 6; copy number 20: 10; copy number 51: 72; copy number 55: 35; copy number 65: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,210 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:176,060,689–177,597,242, 64 genes, copy number 10–17 (within-gene range 4–17) (broad region; genes not listed).
- chr8:8,059,572–8,226,614, 8 genes, copy number 20: AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:9,984,004–12,115,516, 72 genes, copy number 51 (broad region; genes not listed).
- chr8:12,178,697–15,238,431, 57 genes, copy number 9–65 (within-gene range 4–117): ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.
- chr8:99,013,266–145,066,685, 704 genes, copy number 10 (broad region; genes not listed).
- chr9:34,133,157–34,546,996, 19 genes, copy number 9: AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2.
- chr9:34,634,722–34,666,112, 7 genes, copy number 10 (within-gene range 8–10): SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1.
- chr9:34,810,020–34,922,921, 5 genes, copy number 9: AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6.
- chr9:35,909,490–35,958,154, 3 genes, copy number 9: SPAAR, PGAM1P2, OR2S2.
- chr9:36,190,856–36,304,781, 3 genes, copy number 9 (within-gene range 7–9): CLTA, GNE, RNU4-53P.
- chr12:166,856–277,123, 7 genes, copy number 9 (within-gene range 8–9): AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4.
- chr12:974,133–1,647,212, 8 genes, copy number 9 (within-gene range 8–9): AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14.
- chr12:5,948,877–6,270,425, 6 genes, copy number 9: VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5.
- chr12:9,898,673–9,953,336, 3 genes, copy number 9 (within-gene range 7–9): CLEC2A, LINC02470, CLEC12A-AS1.
- chr12:10,111,738–10,572,688, 20 genes, copy number 9: HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446.
- chr12:10,801,532–10,810,168, 3 genes, copy number 10: TAS2R7, TAS2R8, TAS2R9.
- chr12:12,111,952–12,471,233, 10 genes, copy number 9 (within-gene range 8–9): MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5.
- chr12:12,715,058–12,724,011, 3 genes, copy number 9: CDKN1B, AC008115.3, AC008115.1.
- chr12:13,000,451–13,142,521, 4 genes, copy number 9 (within-gene range 8–9): AC023790.2, AC023790.1, FAM234B, GSG1.
- chr12:13,371,089–13,982,002, 3 genes, copy number 9 (within-gene range 7–9): LINC01559, GRIN2B, RNA5SP353.
- chr12:14,169,746–14,502,935, 8 genes, copy number 9: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP.
- chr12:14,914,039–15,348,675, 6 genes, copy number 9 (within-gene range 8–9): ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1.
- chr12:15,255,213–15,903,478, 8 genes, copy number 9: METTL8P1, PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP.
- chr12:16,188,485–16,610,594, 7 genes, copy number 9: SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2.
- chr12:18,242,961–18,648,416, 3 genes, copy number 9 (within-gene range 8–9): PIK3C2G, NDFIP1P1, AC092851.1.
- chr12:21,468,910–21,942,529, 12 genes, copy number 9 (within-gene range 8–9): RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2.
- chr12:22,063,773–23,251,499, 18 genes, copy number 9 (within-gene range 8–9): ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:24,223,233–29,784,759, 109 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr12:30,230,779–30,321,617, 4 genes, copy number 9: LINC02386, AC078776.2, RNA5SP356, AC078776.1.
- chr12:30,628,988–30,996,602, 7 genes, copy number 9 (within-gene range 8–9): IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11.
- chr12:31,244,440–31,591,136, 16 genes, copy number 9 (within-gene range 8–9): AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2.
- chr12:31,627,575–31,803,090, 9 genes, copy number 9–10: AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P.
- chr12:31,876,969–32,646,050, 19 genes, copy number 9: LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr12:32,985,838–33,455,452, 6 genes, copy number 9: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1.
- chr14:22,304,054–66,509,394, 878 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr18:630,886–712,662, 6 genes, copy number 10–11 (within-gene range 6–11): TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2.
- chr18:2,916,994–3,025,566, 8 genes, copy number 11: LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70.
- chr18:3,284,120–3,478,978, 8 genes, copy number 9–10: AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:21,914,369–22,348,252, 12 genes, copy number 9–10: AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr18:23,453,287–25,352,190, 43 genes, copy number 10–15 (within-gene range 5–19): RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
